Somatic mutation profile of tumor specimen TCGA-HT-A4DV-01A (aliquot TCGA-HT-A4DV-01A-11D-A26M-08) from TCGA case TCGA-HT-A4DV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.5 years (18,799 days).
Specimen TCGA-HT-A4DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18ef87a9-b61f-4ce2-ba39-46472001ffc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A4DV-10A (Blood Derived Normal), aliquot TCGA-HT-A4DV-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff7e455d-e463-4fa2-98e3-ba873ae24d73

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- APOBEC4 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV58018154; called by muse, mutect2, varscan2
- CIC | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50571838; called by muse, mutect2
- DENND2C | c.1381C>T p.R461C (on ENST00000393274 / NM_001256404.2; = p.R404C on NM_198459.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs561912187, COSV67922997; called by muse, mutect2
- FHOD1 | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1039772478, COSV50763392; called by muse, mutect2, varscan2
- FICD | c.486G>C p.L162F | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV57209331; called by muse, mutect2
- HSPA4L | c.2382A>C p.E794D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV56547126; called by muse, mutect2, varscan2
- HTRA4 | c.1057A>C p.I353L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV56760373; called by muse, mutect2, varscan2
- SYNE1 | c.6268G>C p.E2090Q (on ENST00000367255 / NM_182961.4; = p.E2097Q on NM_033071.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs374482089, COSV55004599, COSV55007604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- U2AF2 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58273479, COSV58275436; called by muse, mutect2
- XAGE2 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ANKRD23 | c.498A>T p.A166= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV58413061; called by muse, mutect2, varscan2
- HDLBP | c.2898T>G p.A966= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV60499142; called by muse, mutect2, varscan2
- PLXNB3 | c.5334T>C p.N1778= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs781953533, COSV62800017; called by muse, mutect2
- AP000769.3 | chr11:65501694 ins G | 5'Flank (INS) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- MC3R | c.-94G>A | 5'UTR (SNP) | VAF 10/133 reads (8%) | catalogued as rs545319855, COSV54764343; called by muse, mutect2
